Somatic mutation profile of tumor specimen TCGA-G7-A8LE-01A (aliquot TCGA-G7-A8LE-01A-11D-A35Z-10) from TCGA case TCGA-G7-A8LE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.5 years (22,810 days).
Specimen TCGA-G7-A8LE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e4b7cfb-22f8-48fe-8ef3-5b9e42da81d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-A8LE-10A (Blood Derived Normal), aliquot TCGA-G7-A8LE-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22002f52-6cdc-4ff2-8b50-2ce74437e08d

The open-access MAF lists 82 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 51, Silent 17, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 3, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3688T>C p.Y1230H | Missense Mutation (SNP) | VAF 125/232 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913247, CM992180, COSV59256836; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABHD12 | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.82); catalogued as COSV99405516; called by muse, mutect2, varscan2
- ACSF2 | c.1396T>C p.Y466H | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51971936; called by muse, mutect2, varscan2
- AGXT2 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745977837, COSV99183997; called by muse, mutect2, varscan2
- ALOX12 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV99278526; called by muse, mutect2, varscan2
- ANKRD2 | c.538-1G>C p.X180_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100081076; called by muse, mutect2, varscan2
- BAP1 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964585; called by muse, mutect2
- C11orf24 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs759054521; called by pindel, varscan2
- CACNG8 | c.831C>G p.S277R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.763); catalogued as COSV99555194; called by muse, mutect2, varscan2
- CALHM6 | c.761T>A p.M254K | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.014); catalogued as COSV100889478; called by muse, mutect2, varscan2
- CDKN1C | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100532312; called by muse, mutect2, varscan2
- CPEB4 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.379); catalogued as COSV99437788; called by muse, mutect2, varscan2
- DNM3 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 230/297 reads (77%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV100798738; called by muse, mutect2, varscan2
- EPHB3 | c.2973C>G p.N991K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.162); catalogued as rs1378532830, COSV100383326; called by muse, mutect2, varscan2
- ESCO1 | c.2268G>T p.W756C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99332664; called by muse, mutect2, varscan2
- FAT1 | c.1168_1169insTTT p.K390delinsI* | Nonsense Mutation (INS) | VAF 34/77 reads (44%) | catalogued as COSV101499672; called by mutect2, pindel, varscan2
- FLCN | c.1064T>G p.V355G | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99550757; called by muse, mutect2, varscan2
- GDF3 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100325040, COSV100325438; called by muse, mutect2, varscan2
- GJB3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs763321092, COSV64904413; called by muse, mutect2, varscan2
- HASPIN | c.2288A>G p.N763S | Missense Mutation (SNP) | VAF 94/163 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV99561654; called by muse, mutect2, varscan2
- HAT1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 144/363 reads (40%) | catalogued as COSV99908148; called by muse, mutect2, varscan2
- HCFC1 | c.5425G>C p.E1809Q | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV100130037; called by muse, mutect2, varscan2
- IPO8 | c.2279T>G p.L760R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.15); catalogued as COSV99805702; called by muse, mutect2, varscan2
- JAG1 | c.3501del p.A1168Pfs*12 | Frame Shift Del (DEL) | VAF 66/167 reads (40%) | catalogued as COSV99652267; called by mutect2, pindel, varscan2
- KAT2B | c.2247G>A p.M749I | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99769148, COSV99769971; called by muse, mutect2, varscan2
- KMT2D | c.7156C>G p.R2386G | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV56489341, COSV99986356; called by muse, mutect2, varscan2
- LLCFC1 | c.210G>C p.E70D (on ENST00000458732; = p.E39D on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.555); catalogued as rs1410109887, COSV100787022; called by muse, mutect2, varscan2
- LONRF2 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101111072; called by muse, mutect2, varscan2
- LRIG3 | c.2179A>G p.K727E | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV100292880; called by muse, mutect2, varscan2
- LRP2 | c.13124T>G p.I4375S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.165); catalogued as COSV99790555; called by muse, mutect2, varscan2
- MICU1 | c.1406G>C p.W469S (on ENST00000361114 / NM_001195518.2; = p.W475S on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100741961; called by muse, mutect2, varscan2
- MTHFR | c.1436T>C p.I479T | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV100453829; called by muse, mutect2, varscan2
- NEK1 | c.2788A>C p.T930P | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101455911; called by muse, mutect2, varscan2
- NEUROD1 | c.102C>G p.H34Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99716854, COSV99717080; called by muse, mutect2, varscan2
- NLRP14 | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100205490; called by muse, mutect2, varscan2
- NR3C1 | c.2171C>G p.S724C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV51540743, COSV99196849; called by muse, mutect2, varscan2
- OR2B2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100308254; called by muse, mutect2, varscan2
- OVCH1 | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100549301; called by muse, mutect2, varscan2
- P2RY13 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs936533736, COSV99855001; called by muse, mutect2, varscan2
- PAX8 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs199890664, COSV99640189; called by muse, mutect2, varscan2
- PNPT1 | c.2258A>G p.Q753R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV99570563; called by muse, mutect2, varscan2
- PPIP5K2 | c.2330G>C p.G777A | Missense Mutation (SNP) | VAF 156/356 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV100384333, COSV58605919; called by muse, mutect2, varscan2
- RHBDL1 | c.649C>T p.R217C (on ENST00000219551 / NM_001318733.2; = p.R152C on NM_001278720.2) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs778300183, COSV53484702; called by muse, mutect2, varscan2
- RNF207 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 82/103 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933776; called by muse, mutect2, varscan2
- RTL10 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100144309; called by muse, mutect2, varscan2
- SLC2A12 | c.1175A>T p.Y392F | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99260676; called by muse, mutect2, varscan2
- SLC2A13 | c.1494C>G p.Y498* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as rs1438045829, COSV99787304; called by muse, mutect2, varscan2
- SSMEM1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 124/221 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); catalogued as rs371191805, COSV99927873; called by muse, mutect2, varscan2
- SYT13 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV99194871; called by muse, mutect2, varscan2
- TCERG1L | c.1516A>C p.K506Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); catalogued as COSV100894640; called by muse, mutect2, varscan2
- TG | c.6265T>C p.S2089P | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.451); catalogued as COSV99603674; called by muse, mutect2, varscan2
- TMEM45A | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100058719; called by muse, mutect2, varscan2
- TSPAN14 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV100540471; called by muse, mutect2, varscan2
- TSPYL5 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100439168; called by muse, mutect2, varscan2
- VAV1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV58381219; called by muse, mutect2, varscan2
- ZC3H6 | c.960C>G p.N320K | Missense Mutation (SNP) | VAF 174/491 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100674854; called by muse, mutect2, varscan2
- ZNF582 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100019005; called by muse, mutect2, varscan2
- CLP1 | c.173_175del p.D58del | In Frame Del (DEL) | VAF 75/215 reads (35%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.4696_4697del p.P1566Cfs*7 | Frame Shift Del (DEL) | VAF 122/261 reads (47%) | called by mutect2, pindel, varscan2
- GPR101 | c.1297C>A p.Q433K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.437); called by muse, mutect2
- NCKAP5 | c.3933dup p.L1312Sfs*56 | Frame Shift Ins (INS) | VAF 62/173 reads (36%) | called by mutect2, pindel, varscan2
- RACGAP1 | c.43del p.V16Cfs*43 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- SLC2A13 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | called by mutect2, pindel, varscan2
- TMEM174 | c.173del p.G58Afs*26 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | called by mutect2, varscan2
- ZNF80 | c.386_388del p.G129del | In Frame Del (DEL) | VAF 41/101 reads (41%) | called by mutect2, pindel, varscan2
- CHAMP1 | c.1431T>G p.P477= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as COSV100778884; called by muse, mutect2, varscan2
- CIZ1 | c.1716C>A p.P572= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99477172; called by muse, mutect2, varscan2
- DHX33 | c.1410G>A p.A470= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as rs749397000, COSV56578097; called by muse, mutect2, varscan2
- DPF1 | c.864A>G p.L288= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV100831605; called by muse, mutect2, varscan2
- DST | c.4218A>C p.R1406= (on ENST00000361203 / NM_001374722.1; = p.R1080= on NM_001723.6) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99760622; called by muse, mutect2, varscan2
- GUSB | c.1140T>C p.A380= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as COSV100512791; called by muse, mutect2, varscan2
- JAK3 | c.663G>C p.L221= | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV101513035; called by muse, mutect2, varscan2
- LMLN | c.1185G>A p.Q395= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100218925; called by muse, mutect2, varscan2
- MPP2 | c.390G>C p.T130= (on ENST00000461854 / NM_001278372.2; = p.T106= on NM_005374.5) | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs553317360, COSV99290909; called by muse, mutect2, varscan2
- NAV3 | c.1452C>A p.V484= | Silent (SNP) | VAF 105/277 reads (38%) | catalogued as COSV99894724; called by muse, mutect2, varscan2
- OVCH1 | c.2298A>G p.P766= | Silent (SNP) | VAF 107/312 reads (34%) | catalogued as COSV100549304; called by muse, mutect2, varscan2
- PCDHGA2 | c.129C>G p.S43= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99548519; called by muse, mutect2, varscan2
- PIDD1 | c.1660C>T p.L554= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as COSV100204330; called by muse, mutect2, varscan2
- PRKCQ | c.6G>A p.S2= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs201768145, COSV99577696; called by muse, mutect2, varscan2
- SCRN2 | c.915T>C p.L305= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV99274361; called by muse, mutect2, varscan2
- SORCS1 | c.2532T>G p.S844= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as rs1168328047, COSV99550925; called by muse, mutect2, varscan2
- SSTR3 | c.783C>A p.A261= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as COSV100142923; called by muse, mutect2, varscan2
